Somatic mutation profile of tumor specimen ALCH-B3B2-TTP1-A (aliquot ALCH-B3B2-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B3B2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.3 years (22,752 days).
Specimen ALCH-B3B2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6c9776a-2f9e-4faf-bc0a-21e6d4f83124.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3B2-NB1-A (Blood Derived Normal), aliquot ALCH-B3B2-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6710200d-15f6-4491-8843-84ccdef0ca96

The open-access MAF lists 32 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, 3'UTR 2, Frame Shift Ins 1, Nonsense Mutation 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8880G>T p.W2960C | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53739792, COSV53766618, COSV53766871; called by muse, mutect2
- CDKN1B | c.80C>A p.S27* | Nonsense Mutation (SNP) | VAF 12/296 reads (4%) | catalogued as COSV57431591, COSV99963866; called by muse, mutect2
- FASN | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs1231782441; called by muse, mutect2
- TACC2 | c.7685C>G p.S2562C (on ENST00000334433; = p.S640C on NM_006997.4) | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV53290838; called by muse, mutect2
- ACKR1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.147); called by muse, mutect2
- CACNB1 | c.1087C>A p.Q363K | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CPEB1 | c.1826G>T p.G609V (on ENST00000617958; = p.G544V on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- CSMD3 | c.4400A>T p.D1467V (on ENST00000297405 / NM_001363185.1; = p.D1363V on NM_052900.3) | Missense Mutation (SNP) | VAF 19/347 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- CWC22 | c.533dup p.S179Kfs*14 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by mutect2, pindel
- FBN1 | c.3779A>T p.E1260V | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.162); called by muse, mutect2
- GCSAML | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 9/278 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCTD7 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 16/285 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.171); called by muse, mutect2
- KIAA1217 | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 8/244 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- LCA5 | c.733A>T p.N245Y | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MYEOV | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.693); called by muse, mutect2
- RBM12 | c.479C>A p.P160Q | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- RNF115 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SNTG2 | c.829A>T p.R277W | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.319); called by muse, mutect2
- TET2 | c.2138T>A p.F713Y | Missense Mutation (SNP) | VAF 24/670 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2
- ADAR | c.1522C>T p.L508= | Silent (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2, varscan2
- COL9A3 | c.1917C>A p.G639= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV53897745; called by muse, mutect2
- FANCM | c.5229C>A p.S1743= | Silent (SNP) | VAF 12/219 reads (5%) | called by muse, mutect2
- FPR2 | c.528T>C p.C176= | Silent (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- LRRC42 | c.102C>G p.V34= | Silent (SNP) | VAF 28/509 reads (6%) | called by muse, mutect2
- PRIMPOL | c.438C>T p.Y146= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs201667994; called by muse, mutect2, varscan2
- PRKAR1B | c.90C>T p.V30= | Silent (SNP) | VAF 13/181 reads (7%) | catalogued as rs1302688069; called by muse, mutect2
- PTCD1 | c.735C>G p.L245= | Silent (SNP) | VAF 27/444 reads (6%) | called by muse, mutect2
- SPTBN5 | c.10497A>G p.R3499= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, varscan2
- BCS1L | c.*18C>T | 3'UTR (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- INPP4A | c.*15C>G | 3'UTR (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- PITPNB | c.-30C>T | 5'UTR (SNP) | VAF 22/500 reads (4%) | catalogued as rs1463562369, COSV58061800; called by muse, mutect2
- TIAM1 | chr21:31559503 C>T | 5'Flank (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
